Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8286, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8286-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted] Case ID	Gross Description	Microscopic Description	Diagnosis Details
[Redacted]			

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Antrum Tumor size: 8 x 6.5 x 1 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 0/5 positive for metastasis (Regional 0/5) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

	ID

[page 3 of 3]
Excision date	Laterality

Source: NCI Genomic Data Commons file b0f391a4-e2a2-4b24-a183-45a2a8290091 (TCGA-BR-8286.DEA1AB09-0DF6-4D15-9C96-A46FE1FE1408.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).